Gene-level copy-number profile of tumor specimen TCGA-44-6146-01A from TCGA case TCGA-44-6146, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.0 years (23,378 days).
Specimen TCGA-44-6146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e6d25aa5-583a-490f-8b71-aea421f1342d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6146-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/486ad8d0-3d86-47d3-ad41-25b8cb7dc84a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,260; copy number 1: 7,582; copy number 2: 49,899; copy number 3: 289; copy number 4: 168; copy number 5: 1; copy number 8: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-6146-01A-11D-A273-01): tumor purity 0.7, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 8 (within-gene range 2–8): AC244205.1.
- chr2:88,857,161–89,046,466, 20 genes, copy number 8: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr11:91,114,724–91,115,951, 1 gene, copy number 5: OSBPL9P2.

Autosomal genes at a single copy (total copy number 1): 7,443. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
